MMRF case MMRF_2720 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f83f8f26-0ad5-43e9-8993-ee3baa2ceeb4

Demographics
Sex at birth: female; Age at index: 62 years; Vital status: Dead; Days to death: 291 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; ISS stage: I; Days to last known disease status: 291 days; Days to last follow up: 291 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -4, day 291.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- Lactate Dehydrogenase 2.57 µkat/L.
- Beta 2 Microglobulin 0.64 µg/mL.
- Albumin 35 g/L.
- Platelets 154 ×10⁹/L.
- M Protein 4.7 g/dL.
- Absolute Neutrophil 1.93 ×10⁹/L.
- Creatinine 64.5 µmol/L.
- Hemoglobin 5.15 mmol/L.

Other clinical attributes
- Day -4: Weight: 0 kg; Height: 0 cm.

Biospecimens (1 sample)
- Sample MMRF_2720_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
